Somatic mutation profile of tumor specimen MMRF_1157_1_BM_CD138pos (aliquot MMRF_1157_1_BM_CD138pos_T2_KHS5U_L13423) from MMRF case MMRF_1157, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.8 years (25,484 days).
Specimen MMRF_1157_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc79d8f-59c0-4021-a0ad-79f726d0367d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1157_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1157_1_PB_Whole_C1_KHS5U_L13424; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ab6c88e-14ab-4253-9edd-891d1cb83bfe

The open-access MAF lists 142 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 32, Intron 16, Silent 14, 5'Flank 5, Frame Shift Del 3, 5'UTR 3, 3'Flank 2, Splice Site 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRB3 | c.3614G>T p.G1205V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs780355361; called by muse, mutect2, varscan2
- ALPG | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV99779403; called by muse, mutect2
- DENND5B | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.377); catalogued as rs1291794370; called by muse, mutect2, varscan2
- DNAH17 | c.7312C>T p.R2438C | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs769324928, COSV67749293; called by muse, mutect2, varscan2
- DTD1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV66281362; called by muse, mutect2, varscan2
- ERCC6 | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs757008329; called by muse, mutect2, varscan2
- FBXO7 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832945; called by muse, mutect2, varscan2
- FOXA3 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142143651; called by muse, mutect2, varscan2
- GNL3 | c.1092T>G p.F364L | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV56477272; called by muse, mutect2
- HARS1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765994836, COSV56907022; called by muse, mutect2, varscan2
- HDGF | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100625709; called by muse, mutect2
- IGLL5 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.077); catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2
- MYOG | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV54096037, COSV99613979; called by muse, mutect2, varscan2
- NCK1 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56637599; called by muse, mutect2
- NIBAN2 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104394211; called by muse, mutect2, varscan2
- NTRK3 | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62314694; called by muse, mutect2, varscan2
- PRUNE2 | c.4699G>A p.G1567R | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV100944688; called by muse, mutect2, varscan2
- RANBP6 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52388916; called by muse, mutect2
- STAP2 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472526108; called by muse, mutect2
- SUB1 | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV54083463; called by muse, varscan2
- SVIL | c.4700G>A p.R1567H (on ENST00000355867 / NM_021738.3; = p.R1141H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs199941504; called by muse, mutect2, varscan2
- TECTA | c.5672C>T p.T1891M | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs200977539; called by muse, mutect2, varscan2
- TGFBR3 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV53021271, COSV53023837, COSV99282542; called by muse, mutect2, varscan2
- ZMYM6 | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64120072; called by muse, mutect2, varscan2
- ADPRM | c.865T>G p.F289V | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANTXR1 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2
- BHLHA15 | c.263T>G p.M88R | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BTG3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.3940G>C p.G1314R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- COX10 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXXC1 | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DCAF16 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); called by muse, mutect2
- FNTA | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPN2 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD1 | c.5335G>A p.D1779N | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGHMBP2 | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KBTBD12 | c.1184A>T p.K395I | Missense Mutation (SNP) | VAF 191/366 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNH4 | c.2962_2968del p.P988Dfs*16 | Frame Shift Del (DEL) | VAF 13/117 reads (11%) | called by mutect2, pindel, varscan2
- KCNIP4 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIAA2026 | c.3866C>A p.T1289N | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT79 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LAMC1 | c.1898A>T p.Y633F | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- LAMC2 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- NCAM2 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2
- NRK | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NWD1 | c.3779G>T p.C1260F | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OLFML2A | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 91/163 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4Q3 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OR6C1 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR8K1 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2
- PCDHGA4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G5 | c.-10-2A>G | Splice Site (SNP) | VAF 90/365 reads (25%) | called by muse, mutect2, varscan2
- PTPN13 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RPS12 | c.-36G>C | Splice Region (SNP) | VAF 38/478 reads (8%) | called by muse, mutect2
- RPS4X | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SCAPER | c.2116_2117del p.R706Afs*8 | Frame Shift Del (DEL) | VAF 66/192 reads (34%) | called by pindel, varscan2
- SMARCC1 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TDRP | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- TEFM | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFAP2D | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 130/234 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMF1 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- TNS3 | c.144_148del p.Y49Gfs*10 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- TPP2 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- TRPC3 | c.2188A>T p.T730S (on ENST00000379645 / NM_001366479.2; = p.T657S on NM_003305.2) | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UIMC1 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- WDR90 | c.2286C>G p.S762R | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZC2HC1B | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF407 | c.5828T>A p.V1943D | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF443 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 169/334 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACOT12 | c.591C>T p.H197= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as rs149420016; called by muse, mutect2, varscan2
- CLCN1 | c.297T>C p.C99= | Silent (SNP) | VAF 74/132 reads (56%) | catalogued as rs1364971326; called by muse, mutect2, varscan2
- DAAM1 | c.2382G>A p.V794= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as rs752501031; called by muse, mutect2, varscan2
- DIXDC1 | c.2019A>C p.V673= (on ENST00000440460 / NM_001037954.4; = p.V462= on NM_033425.4) | Silent (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- HKDC1 | c.1218C>T p.L406= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as COSV63578163; called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 93/188 reads (49%) | catalogued as rs577917177; called by muse, varscan2
- LRATD1 | c.376C>T p.L126= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1313130382; called by muse, mutect2
- LRCH1 | c.540A>G p.L180= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- NTSR1 | c.144G>A p.A48= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs1419894159, COSV65138422; called by muse, mutect2, varscan2
- PCDHGA9 | c.1911G>A p.A637= | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as rs370856862, COSV53995926; called by muse, mutect2, varscan2
- PHEX | c.978C>G p.L326= | Silent (SNP) | VAF 97/98 reads (99%) | called by muse, mutect2, varscan2
- SEMA6B | c.174C>T p.P58= | Silent (SNP) | VAF 79/155 reads (51%) | catalogued as rs1416147415; called by muse, mutect2, varscan2
- SORBS1 | c.3351G>A p.R1117= | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as rs373494742; called by muse, mutect2, varscan2
- XPNPEP1 | c.1857T>C p.S619= | Silent (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- ABCC10 | c.162-362A>G | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700858 C>T | 3'Flank (SNP) | VAF 128/275 reads (47%) | called by muse, mutect2, varscan2
- ARX | c.*330A>G | 3'UTR (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- BBX | c.*4766A>C | 3'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- BIRC3 | c.*1799C>T | 3'UTR (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- BRS3 | c.*408A>C | 3'UTR (SNP) | VAF 22/35 reads (63%) | called by muse, mutect2, varscan2
- C1orf21 | c.*8633A>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | catalogued as rs900754966; called by muse, mutect2, varscan2
- CHRAC1 | c.*897T>C | 3'UTR (SNP) | VAF 27/50 reads (54%) | catalogued as rs1237186701; called by mutect2, varscan2
- DCAF6 | chr1:167936654 G>A | 5'Flank (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*2121G>A | 3'UTR (SNP) | VAF 9/93 reads (10%) | catalogued as rs1420240285; called by muse, mutect2, varscan2
- DENND1B | c.*1341A>T | 3'UTR (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2
- DENND1B | c.*1339T>A | 3'UTR (SNP) | VAF 58/112 reads (52%) | called by muse, mutect2
- DSEL | c.*640A>T | 3'UTR (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- EDIL3 | c.*326A>T | 3'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- ERI2 | chr16:20806595 C>T | 5'Flank (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- EWSR1 | c.*26T>C | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- FAM126B | c.153+74T>C | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- FAM133A | c.*2063del | 3'UTR (DEL) | VAF 19/25 reads (76%) | called by mutect2, pindel, varscan2
- FAM177A1 | c.96+115G>C | Intron (SNP) | VAF 66/232 reads (28%) | called by muse, mutect2
- FAM71C | c.-287G>T | 5'UTR (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- FLT3 | c.*395T>C | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- IFT74 | c.*199C>T | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- IQSEC3 | c.-25C>G | 5'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2
- KIF25 | c.317+2079C>T | Intron (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- KLHL4 | c.*857G>A | 3'UTR (SNP) | VAF 4/39 reads (10%) | catalogued as rs889207124; called by muse, mutect2, varscan2
- KLRK1 | c.*61C>T | 3'UTR (SNP) | VAF 70/242 reads (29%) | called by muse, mutect2
- MAN1C1 | c.*181C>T | 3'UTR (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- MECP2 | c.*5418T>G | 3'UTR (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- MYO1F | c.3+51C>T | Intron (SNP) | VAF 69/119 reads (58%) | called by muse, mutect2, varscan2
- NCKAP5 | c.*1007C>T | 3'UTR (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- NGLY1 | c.246+57T>C | Intron (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+1129T>A | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+4034A>T | Intron (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- RAB8B | c.*544A>C | 3'UTR (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- RBM34 | c.*458G>A | 3'UTR (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158906 C>T | 5'Flank (SNP) | VAF 9/28 reads (32%) | catalogued as rs1454104233; called by muse, mutect2, varscan2
- RTKN | c.111+2025A>T | Intron (SNP) | VAF 83/298 reads (28%) | called by muse, mutect2, varscan2
- SCUBE2 | c.256+27G>C | Intron (SNP) | VAF 64/310 reads (21%) | called by muse, mutect2, varscan2
- SEC24A | c.1779+461G>C | Intron (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- SGK1 | chr6:134175582 G>A | 5'Flank (SNP) | VAF 84/141 reads (60%) | called by muse, mutect2, varscan2
- SLC39A13 | c.415+25C>T | Intron (SNP) | VAF 29/69 reads (42%) | catalogued as rs1289520959; called by muse, mutect2, varscan2
- SLC39A8 | c.-253-120_-253-119insT | Intron (INS) | VAF 62/238 reads (26%) | called by mutect2, pindel, varscan2
- SLC7A2 | c.*3142G>A | 3'UTR (SNP) | VAF 87/186 reads (47%) | catalogued as rs1391205085; called by muse, mutect2, varscan2
- STPG4 | c.519+822C>T | Intron (SNP) | VAF 26/52 reads (50%) | catalogued as rs1189702710; called by muse, mutect2, varscan2
- TBR1 | c.*7C>T | 3'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2
- TERT | c.2843+39T>C | Intron (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- TRAF3 | c.*2673G>A | 3'UTR (SNP) | VAF 78/168 reads (46%) | catalogued as rs1019393679; called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3295G>A | Intron (SNP) | VAF 38/90 reads (42%) | catalogued as rs1468730619, COSV100211530; called by muse, varscan2
- UAP1L1 | chr9:137086446 C>T | 3'Flank (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- UBN1 | chr16:4847451 G>C | 5'Flank (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- VGLL3 | c.*3186A>T | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- VGLL3 | c.*1250T>C | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- WDR36 | c.*1340G>C | 3'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- YWHAB | c.*1561G>A | 3'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as rs1050666548; called by muse, mutect2, varscan2
- ZDHHC18 | c.*581G>T | 3'UTR (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- ZNF398 | c.*3193A>G | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- ZNF641 | c.*1313G>C | 3'UTR (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- ZNF729 | c.-58G>T | 5'UTR (SNP) | VAF 8/168 reads (5%) | catalogued as rs1460953728; called by muse, mutect2
